Somatic mutation profile of tumor specimen TCGA-UD-AAC7-01A (aliquot TCGA-UD-AAC7-01A-11D-A39R-32) from TCGA case TCGA-UD-AAC7, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 47.4 years (17,299 days).
Specimen TCGA-UD-AAC7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c15f7957-b574-4c6c-a84e-1a4480c0171f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UD-AAC7-10A (Blood Derived Normal), aliquot TCGA-UD-AAC7-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db77cb2d-0c54-468c-b875-c41bc936b7c2

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSRA | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1488447615; called by muse, mutect2, varscan2
- NEB | c.17867C>T p.T5956M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770889470, COSV99413890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF2 | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | catalogued as CS045482, COSV100099774; called by muse, mutect2, varscan2
- OTUD7A | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as rs377428324; called by muse, mutect2, varscan2
- TP53 | c.511del p.E171Rfs*3 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | catalogued as COSV52671445, COSV52701260, COSV52703282; called by mutect2, pindel, varscan2
- TSPYL2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1375956619; called by muse, mutect2
- ZNF579 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.184); catalogued as rs781120747; called by muse, mutect2, varscan2
- ZNF597 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57084263; called by muse, mutect2, varscan2
- ERCC3 | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MORN1 | c.-7_1dup p.M1? | Frame Shift Ins (INS) | VAF 15/31 reads (48%) | called by mutect2, varscan2
- NFKBIE | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- OR8H2 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZNF304 | c.926G>C p.C309S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBBP | c.6120A>T p.I2040= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs1470844679; called by muse, mutect2, varscan2
- CSMD1 | c.6804A>C p.A2268= (on ENST00000520002; = p.A2267= on NM_033225.6) | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- ISYNA1 | c.834G>T p.G278= | Silent (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- OR1J2 | c.549C>A p.A183= | Silent (SNP) | VAF 71/229 reads (31%) | catalogued as COSV58944942; called by muse, mutect2, varscan2
- TNS4 | c.723G>A p.S241= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs376473679; called by muse, mutect2, varscan2
- UTP20 | c.204C>T p.Y68= | Silent (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
